Somatic mutation profile of tumor specimen 0DQMPR from CCDI case PBCFBL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 15.0 years (5,467 days).
Specimen 0DQMPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9834c4d4-7660-471c-8fc5-453d5a9b8863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQMQW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/217ff075-de61-4250-8a95-0915f318b659

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Intron 3, Silent 3, Frame Shift Del 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSL3 | c.1372C>T p.R458* (on ENST00000312196 / NM_078629.4; = p.R292* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 102/796 reads (13%) | catalogued as rs1555907620, COSV56495389; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.3562G>A p.A1188T | Missense Mutation (SNP) | VAF 184/824 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs281875196, CM122563, COSV61807096, COSV61812080; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DCAF8L1 | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 146/610 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101491465; called by muse, mutect2, varscan2
- FAM120C | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 278/737 reads (38%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.006); catalogued as rs1306829749, COSV60261114; called by muse, mutect2, varscan2
- PTCH1 | c.2908G>T p.E970* | Nonsense Mutation (SNP) | VAF 293/1094 reads (27%) | catalogued as CM045082, COSV59496165; called by muse, mutect2, varscan2
- SBK3 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60015586; called by muse, mutect2, varscan2
- SCN2A | c.5921C>T p.S1974L | Missense Mutation (SNP) | VAF 169/1474 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51840801; called by muse, mutect2, varscan2
- USP20 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs769591958, COSV59611093; called by muse, mutect2, varscan2
- EDNRA | c.1112T>G p.F371C | Missense Mutation (SNP) | VAF 127/1298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- KIF4A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 176/458 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LAMB1 | c.4206_4222delinsGACC p.G1403Tfs*46 | Frame Shift Del (DEL) | VAF 138/963 reads (14%) | called by pindel, varscan2*
- MXRA7 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 22/142 reads (15%) | PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PANX3 | c.991_993del p.L331del | In Frame Del (DEL) | VAF 282/898 reads (31%) | called by pindel, varscan2
- PTCH1 | c.338_339del p.A113Gfs*26 | Frame Shift Del (DEL) | VAF 218/638 reads (34%) | called by pindel, varscan2
- SLC11A2 | c.843G>T p.Q281H (on ENST00000394904 / NM_001379455.1; = p.Q252H on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/605 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- SLC9A7 | c.680+2T>C p.X227_splice | Splice Site (SNP) | VAF 84/873 reads (10%) | called by muse, mutect2, varscan2
- ULK3 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPO1 | c.1324A>T p.R442* | Nonsense Mutation (SNP) | VAF 368/1048 reads (35%) | called by muse, mutect2, varscan2
- ARAF | c.837C>T p.R279= | Silent (SNP) | VAF 186/512 reads (36%) | catalogued as rs370587460; called by muse, mutect2, varscan2
- CEL | c.2034C>T p.D678= (on ENST00000673714; = p.D675= on NM_001807.6) | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as rs1208099811; called by muse, mutect2, varscan2
- NME8 | c.486G>A p.P162= | Silent (SNP) | VAF 72/890 reads (8%) | catalogued as rs199713986, COSV52249073, COSV52256478; ClinVar: likely benign; called by muse, mutect2
- ABI3BP | c.1577-9206C>T | Intron (SNP) | VAF 314/1008 reads (31%) | catalogued as rs1165019836; called by muse, mutect2, varscan2
- MAP3K14 | c.1821+97G>C | Intron (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- RNH1 | c.273-49G>A | Intron (SNP) | VAF 69/146 reads (47%) | catalogued as rs1160993405; called by muse, mutect2, varscan2
